Somatic mutation profile of tumor specimen MP2PRT-PASVNV-TMP1-A (aliquot MP2PRT-PASVNV-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PASVNV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,257 days).
Specimen MP2PRT-PASVNV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 61e678a3-f569-4f7d-b713-0ad8c4e1e680.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASVNV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASVNV-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/207f9e1d-69e1-49da-bfc3-3f81e4c3a594

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 9, Silent 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC253536.7 | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 22/436 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as rs150924512; called by muse, mutect2
- GALNT17 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 36/482 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.124); catalogued as rs751565301, COSV61145992; called by muse, mutect2
- KLHL29 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 40/794 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.563); catalogued as rs926293779; called by muse, mutect2
- TRPM5 | c.2788C>T p.R930C | Missense Mutation (SNP) | VAF 58/383 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.931); catalogued as rs767065804; called by muse, mutect2, varscan2
- FAT2 | c.2830T>G p.L944V | Missense Mutation (SNP) | VAF 26/572 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.09); called by muse, mutect2
- PRKCQ | c.1274C>T p.T425M | Missense Mutation (SNP) | VAF 17/626 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- STK31 | c.1385C>G p.S462* | Nonsense Mutation (SNP) | VAF 11/285 reads (4%) | called by muse, mutect2
- UNC80 | c.9590C>T p.S3197F | Missense Mutation (SNP) | VAF 26/630 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.082); called by muse, mutect2
- XYLT2 | c.195C>G p.D65E | Missense Mutation (SNP) | VAF 78/594 reads (13%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.239); called by muse, varscan2
- ZXDA | c.1357G>A p.D453N | Missense Mutation (SNP) | VAF 28/438 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- ASF1A | c.456T>C p.N152= | Silent (SNP) | VAF 101/343 reads (29%) | catalogued as rs1230804820; called by muse, mutect2, varscan2
- DPP10 | c.762G>T p.L254= | Silent (SNP) | VAF 162/364 reads (45%) | catalogued as COSV100066393; called by muse, mutect2, varscan2
- HOXA3 | c.1176C>G p.A392= | Silent (SNP) | VAF 40/856 reads (5%) | called by muse, mutect2
